TCGA case TCGA-FS-A1ZC — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Essen. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b1739cb5-09bc-414a-8f05-c66d2cb9868d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 51 years; Vital status: Dead; Days to death: 10,870 days (29.8 years).

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: metastasis; Age at diagnosis: 79.7 years (29,093 days); Days to diagnosis: 10,250 days (28.1 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 51.6 years (18,843 days); Year of diagnosis: 1978; AJCC staging edition: 1st; AJCC pathologic T: TX; AJCC pathologic N: N0; AJCC pathologic M: M0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Trunk.
   Recorded as not given: Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 2 of this record; Age at diagnosis: 79.9 years (29,177 days); Days to diagnosis: 10,334 days (28.3 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 10,334 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 10,870 days (29.8 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FS-A1ZC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 470 mg.
  Slide TCGA-FS-A1ZC-06A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-FS-A1ZC-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FS-A1ZC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Radiation therapy to primary: No; Primary location: Distant Metastasis; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No; Ifn treatment 90 days prior to resection: Yes.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.
- Stage record: AJCC pathologic tumor stage: I/ii nos.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 10,870 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 10,870 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 10,334 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FS-A1ZC-06A-11D-A191-01): tumor purity 0.89, ploidy 3.09, whole-genome doublings 1.
